Somatic mutation profile of tumor specimen 0DLX59 from CCDI case PBBZXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Granulosa cell tumor, malignant; Tissue or organ of origin: Ovary; Age at diagnosis: 17.6 years (6,443 days).
Specimen 0DLX59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f8b6544-ee52-4383-843e-84fdec9fc1bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/420b5223-8892-42f2-a7f3-57abe79e3238

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.3583A>G p.K1195E | Missense Mutation (SNP) | VAF 189/1278 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99663027; called by muse, mutect2, varscan2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs1554342786; called by mutect2, pindel
- SMOC1 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 63/719 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as rs192204434; called by muse, mutect2
- FLNC | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- LAMA3 | c.7886C>T p.T2629I (on ENST00000313654 / NM_198129.4; = p.T1020I on NM_000227.6) | Missense Mutation (SNP) | VAF 150/1652 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ELK3 | c.789C>T p.A263= | Silent (SNP) | VAF 80/1498 reads (5%) | catalogued as rs756478247, COSV99957817; called by muse, mutect2
- HSPB8 | c.*90G>A | 3'UTR (SNP) | VAF 54/375 reads (14%) | called by muse, mutect2, varscan2
